Somatic mutation profile of tumor specimen MBCProject_2517_T1_WES (aliquot MBCProject_2517_T1_WES_1) from CMI case MBCProject_2517, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 33.3 years (12,146 days).
Specimen MBCProject_2517_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d3b9aa8-82a9-4926-a64f-5b53cc8a68d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2517_SALIVA (Saliva), aliquot MBCProject_2517_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf1ea33-9f0b-4e0d-9bce-42ddcbcd2be9

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 136/287 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 112/370 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.3748C>T p.R1250W (on ENST00000326724 / NM_001080395.3; = p.R1147W on NM_004920.2) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs755745477; called by muse, mutect2, varscan2
- ASZ1 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs963191847; called by muse, mutect2, varscan2
- CCDC158 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs749566655, COSV66355210; called by muse, mutect2, varscan2
- CHST3 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1483422482; called by muse, mutect2, varscan2
- COLQ | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 103/783 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1008156537, COSV67525470; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEPDC1B | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99409628; called by muse, mutect2, varscan2
- FBF1 | c.3059G>A p.R1020Q (on ENST00000586717; = p.R1035Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs768113815; called by muse, mutect2, varscan2
- GARNL3 | c.2710G>T p.E904* | Nonsense Mutation (SNP) | VAF 40/244 reads (16%) | catalogued as COSV59225191; called by muse, mutect2, varscan2
- GPR101 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs768753006, COSV53237353; called by muse, mutect2, varscan2
- IL2RA | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV99060841, COSV99906585; called by muse, mutect2, varscan2
- KLHL41 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 36/176 reads (20%) | catalogued as COSV52929709; called by muse, mutect2, varscan2
- TMEM132D | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV101398472; called by muse, mutect2, varscan2
- TUBB2A | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 73/465 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs1253543318; called by muse, mutect2, varscan2
- UBR1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV51931162; called by muse, mutect2
- WNK3 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs781785725, COSV63614067; called by muse, mutect2, varscan2
- AC011005.1 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 122/587 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKFN1 | c.2853C>A p.H951Q (on ENST00000653862; = p.H804Q on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ANKFN1 | c.2854C>G p.Q952E (on ENST00000653862; = p.Q805E on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ATG2A | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CIITA | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CR1L | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 90/605 reads (15%) | called by muse, mutect2, varscan2
- FBXL13 | c.1976A>T p.Q659L | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FBXO28 | c.860C>G p.T287S | Missense Mutation (SNP) | VAF 71/483 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FOXO6 | c.1123T>G p.L375V | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.67); called by muse, mutect2, varscan2
- GBA | c.182A>T p.Y61F | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- LAG3 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- NXPE3 | c.258C>A p.H86Q | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLG | c.2855G>A p.G952D | Missense Mutation (SNP) | VAF 102/456 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RENBP | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLX4IP | c.197C>G p.S66* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- ZC3H13 | c.3700G>C p.D1234H | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- ZMYM4 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ARX | c.180G>A p.P60= | Silent (SNP) | VAF 144/752 reads (19%) | catalogued as rs773234584; called by muse, mutect2, varscan2
- CHRM3 | c.1374C>T p.F458= | Silent (SNP) | VAF 16/291 reads (5%) | called by muse, mutect2
- GPR50 | c.1311C>G p.V437= | Silent (SNP) | VAF 57/208 reads (27%) | catalogued as rs1443385893; called by muse, mutect2, varscan2
- KMT2D | c.6399C>T p.A2133= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs771111125; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH13 | c.318C>G p.L106= | Silent (SNP) | VAF 78/241 reads (32%) | catalogued as COSV52829509, COSV99355534; called by muse, mutect2, varscan2
- NUP133 | c.3066G>A p.A1022= | Silent (SNP) | VAF 34/239 reads (14%) | catalogued as rs370240365; called by muse, mutect2, varscan2
- PDE2A | c.2331C>T p.F777= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as COSV57803571; called by muse, mutect2, varscan2
- RTL1 | c.2439C>T p.I813= | Silent (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- SLC38A7 | c.1173C>T p.I391= | Silent (SNP) | VAF 106/479 reads (22%) | catalogued as rs766440636; called by muse, mutect2, varscan2
- TOGARAM1 | c.1881T>C p.G627= | Silent (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
